Gene-level copy-number profile of tumor specimen HTMCP-03-06-02037-01A from CGCI case HTMCP-03-06-02037, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G3.
Specimen HTMCP-03-06-02037-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 302bc169-baf7-474b-9dc1-a5da526e4cfb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02037-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/f66e320e-0de5-4c86-adba-f3479694a2a3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 4,326; copy number 2: 46,599; copy number 3: 4,344; copy number 4: 2,056; copy number 5: 597; copy number 6: 472.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:52,488,993–52,587,095, 2 genes: AL137058.1, AL137058.3.
- chr13:57,314,739–57,315,909, 1 gene: SLC25A5P4.
- chr19:1,177,558–1,228,431, 2 genes (within-gene range 0–1): STK11, HMGB2P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,069 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:172,505,508–198,123,232, 506 genes, copy number 5–6 (broad region; genes not listed).
- chr6:157,289,025–157,324,477, 3 genes, copy number 6: TMEM242, LDHAL6FP, AL390955.2.
- chr14:22,112,347–22,499,749, 55 genes, copy number 5: TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr19:27,638,483–40,465,764, 477 genes, copy number 5–6 (broad region; genes not listed).
- chr22:49,414,524–50,085,426, 27 genes, copy number 5: C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, AL023802.1, RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821, IL17REL, TTLL8, MLC1.

Autosomal genes at a single copy (total copy number 1): 4,326. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
